Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A3WV, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A3WV-01A (Primary Tumor).

[page 1 of 5]
MRN
Name
Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. LEFT PELVIC LYMPH NODES-
- B. RIGHT PELVIC LYMPH NODES-
- C. LEFT DISTAL URETER -FS-
- D. RIGHT DISTAL URETER -FS-
- E. BLADDER UTERUS, FALLOPIAN TUBES, OVARIES, ANTERIOR VAGINAL WALL-
- F. MESENTERIC LYMPH NODE-

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES-
- NO CARCINOMA SEEN IN THREE LYMPH NODES (0/3).
- B. RIGHT PELVIC LYMPH NODES-
- NO CARCINOMA SEEN IN THREE LYMPH NODES (0/3).
- C. LEFT DISTAL URETER -FS-
- NO CARCINOMA SEEN.

- D. RIGHT DISTAL URETER -FS-
- NO CARCINOMA SEEN.

E. BLADDER UTERUS, FALLOPIAN TUBES, OVARIES, ANTERIOR VAGINAL WALL-

INVASIVE CARCINOMA, HIGH GRADE.

TUMOR SITE: APEX, URINARY BLADDER.

HISTOLOGIC TYPE: UROTHELIAL.

SQUAMOUS DIFFERENTIATION: FOCALLY PRESENT.

GLANDULAR DIFFERENTIATION: NOT PRESENT.

ICD-O-3

carcinoma, urothelial, NOS

8/20/3

Site: bladder, NOS

C07.9 5-11-12

Rp

Pre

MD
5/9/12

[page 2 of 5]
TUMOR SIZE: 3.5 CM.

HISTOLOGIC GRADE: 3/3.

DEPTH OF INVASION: OUTER LIMIT OF MUSCULARIS PROPRIA (NEARLY 100%).

SPECIMEN TYPE: RADICAL CYSTECTOMY, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY.

TNM STAGE: pT2b, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 7

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

ASSOCIATED EPITHELIAL LESIONS: UROTHELIAL CARCINOMA IN SITU IDENTIFIED.

NO TUMOR SEEN AT MARGINS.

ATROPHIC OVARIES WITH CORTICAL INCLUSION CYSTS. BILATERAL BENIGN PARATUBAL CYSTS. ATROPHIC ENDOMETRIUM. LEIOMYOMAS.
S. MESENTERIC LYMPH NODE-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
(

Signed Others

Frozen Section

A. LEFT AND RIGHT DISTAL URETERS: NO CARCINOMA SEEN.

Frozen section performed by Dr.

Case Clinical Information

BLADDER TUMOR

Gross Description

A. Received in formalin labeled with the patient's name and

Prepar.

[page 3 of 5]
"left pelvic lymph nodes" is an aggregate of lobulated fibroadipose tissue measuring 3 x 3 x 3 cm in compact aggregate. Three potential lymph nodes are bisected and separately submitted in A1-A3.

B. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" are multiple fragments of lobulated fibroadipose tissue measuring 3 x 3 x 3 cm in compact aggregate. Three potential lymph nodes are bisected and separately submitted in B1-B3.

C. Received in formalin labeled with the patient's name and "left distal ureter FS" are two brown-tan tissues, each measuring 4 x 3 mm. Material totally submitted in C1.

D. Received in formalin labeled with the patient's name and "right distal ureter FS" is irregular gray-tan tissue measuring 6 x 5 x 1 mm thick. Specimen totally submitted in D1.

E. Received in formalin labeled with the patient's name and "Bladder, uterus, fallopian tube, ovaries, anterior vaginal wall" is a specimen to include the described organs, measuring 11 cm superior to inferior, 9 cm anterior to posterior, 9 cm right to left. The specimen has been inked blue on the right, black on the left. The bladder cavity measures 2 cm right to left, 3 cm superior to inferior, 1.5 cm anterior to posterior. The bladder mucosa is congested and edematous, and a conspicuous, firm, uniformly pale tan, bulging tumor is noted at the apex. The tumor measures 3.5 x 3.5 x 3.5 cm in greatest dimensions. The right and left ureters are deeply retracted and are not sampled since their resection margins are demonstrated in "C" and "D". The specimen includes the urethra, measuring 3 cm in length, and the anterior vaginal wall, measuring 6 cm superior to inferior and up to 3.5 cm in width superiorly with the anterior vaginal wall and distal urethra connected by a narrow strip of mucosa. The included uterus is 6.5 cm superior to inferior, 4 cm right to left, and 3 cm anterior to posterior. The cervix is 3 cm in diameter with a linear 6 mm os. The right fallopian tube is 5 x 0.3 cm. Right ovary is normally atrophic and measures 1.5 x 1.5 x 0.9 cm. The left fallopian tube is 4 x 0.3 cm in diameter. Normally atrophic left ovary measures 1.5 x 1 x 0.7 cm. The endometrial cavity is distorted by an apparent anterior 1.4 cm fibroid-like tumor with the cavity measuring 1.2 cm in width and 1.5 cm in length. The endometrium appears pale tan and appears to measure less than 1 mm thick. A possible second subserosal fibroid is noted at the left posterior aspect. Section code: E1-shaved distal resection margin to include distal urethra and inferior aspect of anterior vaginal wall; E2-E4-additional cross sections urethra to vaginal wall proceeding inferior to superior to include majority of urethra; E5-shaved residual left vaginal wall resection margin; E6-shaved residual right vaginal wall

[page 4 of 5]
resection margin; E7-E8=entire left tube and ovary;
E9-E10=entire right tube and ovary; E11=duplicate sections of
posterior cervix; E12-E13=duplicate full thickness sections
posterior uterine wall to include 1.2 cm fibroid-like tumor;
E14=anterior cervix including anterior vaginal wall;
E15=anterior uterine wall full thickness section; E16=anterior
subserosal fibroid-like tumor; E17-E20=bladder dome tumor in
relationship to inked surgical margin and inked free peritoneal
surface and comes within 3 mm of the inked right lateral
surgical resection margin (E20).

7. Received in formalin labeled with the patient's name and
"mesenteric lymph node" is a moderately firm yellow-tan tissue
measuring 4 mm in greatest dimension. The specimen is totally
submitted in F1.

PROCEDURE

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
E. AA ROUTINE H&E X1 BLOCK.5
H&E X1 A RESULTS
E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
E. AA ROUTINE H&E X1 BLOCK.7
H&E X1

Prepared for

[page 5 of 5]
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1
E. AA ROUTINE H&E X1 BLOCK.9
H&E X1
E. AA ROUTINE H&E X1 BLOCK.10
H&E X1
E. AA ROUTINE H&E X1 BLOCK.11
H&E X1
E. AA ROUTINE H&E X1 BLOCK.12
H&E X1
E. AA ROUTINE H&E X1 BLOCK.13
H&E X1
E. AA ROUTINE H&E X1 BLOCK.14
H&E X1
E. AA ROUTINE H&E X1 BLOCK.15
H&E X1
E. AA ROUTINE H&E X1 BLOCK.16
H&E X1
E. AA ROUTINE H&E X1 BLOCK.17
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.18
H&E X1
E. AA ROUTINE H&E X1 BLOCK.19
H&E X1
E. AA ROUTINE H&E X1 BLOCK.20
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1

Prepared for C

Source: NCI Genomic Data Commons file 1241b39f-ec7d-4a19-ba3d-e32d2b97f4c3 (TCGA-K4-A3WV.A3D8B88A-51FB-44D2-8E24-096107D60058.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).